Surgical pathology report (de-identified scan), TCGA case TCGA-29-1702, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1702-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Surg Path

CLINICAL HISTORY:

Abdominal/pelvic swelling. [REDACTED] ? ovarian/GI. [REDACTED]

CGA-29-1702

GROSS EXAMINATION:

A. "Omentum (AF1)", received fresh for frozen section is a 13.3 x 8.5 x 3.0 cm aggregate of yellow-tan finely lobulated adipose tissue with a 4.5 x 4.0 x 1.3 cm firm, tan, ill-defined mass. Representative is frozen as AF1, frozen remnant is submitted in block A1. An additional representative section is submitted in block A2.

B. "Omentum", received fresh and placed in formalin is a 14.0 x 9.0 x 3.0 cm aggregate of yellow-tan fibroadipose tissue with multiple firm, tan masses, up to 5.0 x 2.5 x 1.5 cm. Representative sections are submitted in blocks B1-2.

C. "Right gutter", received fresh and placed in formalin is a 2.5 x 1.0 x 0.4 cm fragment of yellow-tan tissue which is entirely submitted in block C1.

D. "Right tube and ovary", received fresh and placed in formalin is a 10.8 gram specimen consisting of a 2.5 x 0.5 x 0.5 cm grossly unremarkable ovary and an attached 3.7 cm long, 0.4 cm in diameter fimbriated fallopian tube. No lesions are grossly identified. The entire ovary and representative of fallopian tube is submitted in blocks D1-2.

E. "Left pelvic sidewall peritoneum", received fresh and placed in formalin is a 3.2 x 3.2 x 2.0 cm fragment of red-tan tissue. There are innumerable red-tan, papillary excrescences on the surface of the specimen. Representative sections in E1-2.

F. "Rectal sigmoid", received fresh and placed in formalin is a 17.0 cm long, 2.0 cm in diameter segment of large bowel. The outer wall is diffusely studded with red-tan papillary excrescences. There is a firmly adherent 4.5 cm long, 0.4 cm in diameter fimbriated fallopian tube which is also studded with red-tan papillary excrescences. No ovary is identified. Several diverticula up to 2.2 cm in depth are identified, however, no other mucosal lesions are identified.

BLOCK SUMMARY:

F1- bowel margins
F2- bowel wall
F3- diverticula
F4- fallopian tube
F5-6- adherent soft tissue surrounding fallopian tube

G. "Donut", received fresh and placed in formalin is a 2.7 cm in diameter circular disc with an attached 6.0 cm long metal probe with an adherent fragment of red-tan soft tissue. There is also a 3.0 x 2.0 x 0.3 cm fragment of pink-tan tissue (G1).

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- adenocarcinoma with Psammoma bodies, consistent with ovarian or peritoneal primary [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

[REDACTED]

[page 2 of 2]
****REVISED DIAGNOSIS**:**
REVISED DIAGNOSIS (CORRECTION OF SPECIMEN CODES).
THERE IS NO CHANGE IN DIAGNOSES)

DIAGNOSIS:
SEROUS ADENOCARCINOMA, FIGO GRADE 3, CONSISTENT WITH AN ORIGIN IN OVARY,
INVOLVING:

- A. OMENTUM.
- B. OMENTUM.
- C. RIGHT GUTTER
- D. SURFACE OF RIGHT OVARY (10gm, 2cm).
- E. LEFT PELVIC SIDE WALL PERITONEUM.
- F. RECTOSIGMOID COLON, SEROSA, AND PERISEROSAL FAT.

TCGA-29-1702

THE FOLLOWING SPECIMENS ARE FREE OF TUMOR:

- D. RIGHT FALLOPIAN TUBE
- F. LEFT FALLOPIAN TUBE.
- G. DONUT.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

DIAGNOSIS:
SEE REVISED DIAGNOSES

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file f137c139-024e-4ba5-88c0-fbb0b89610a5 (TCGA-29-1702.F825BB6C-AFC2-48EA-9286-09C09C7E9918.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).